Gene-level copy-number profile of tumor specimen TCGA-AX-A3FX-01A from TCGA case TCGA-AX-A3FX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 69.2 years (25,260 days).
Specimen TCGA-AX-A3FX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.48c9e2b3-6091-4eff-b7cd-4d6abc9492df.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AX-A3FX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9add52f8-8006-4d19-9b22-4078ee924080

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 45; copy number 2: 6,582; copy number 3: 6,625; copy number 4: 39,593; copy number 5: 2,667; copy number 6: 2,809; copy number 7: 651; copy number 8: 605; copy number 9: 127; copy number 10: 94; copy number 11: 11; copy number 18: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AX-A3FX-01A-11D-A227-01): tumor purity 0.81, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 237 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:4,136,644–4,945,383, 5 genes, copy number 11: AC012445.1, NPM1P48, LINC01249, AC092169.1, RNU6-649P.
- chr3:23,878,981–24,103,238, 6 genes, copy number 9: ARL4AP4, NKIRAS1, RPL15, NR1D2, LINC00691, NPM1P23.
- chr3:132,175,402–132,539,032, 6 genes, copy number 10 (within-gene range 4–10): PSMC2P1, RPL7P16, ACP3, AC020633.1, NIP7P2, DNAJC13.
- chr3:142,145,454–142,225,592, 2 genes, copy number 11: RNU6-425P, GK5.
- chr3:168,858,659–169,038,416, 5 genes, copy number 18: RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr4:849,276–1,028,972, 7 genes, copy number 9: GAK, TMEM175, DGKQ, SLC26A1, IDUA, FGFRL1, AC019103.1.
- chr4:15,778,275–16,227,410, 8 genes, copy number 9 (within-gene range 6–9): CD38, HPRT1P1, FGFBP1, FGFBP2, PROM1, AC108063.2, TAPT1, AC108063.1.
- chr4:16,256,308–16,256,555, 1 gene, copy number 9: RPS21P4.
- chr6:106,784,125–107,115,515, 4 genes, copy number 11 (within-gene range 8–11): MIR587, CD24, MTRES1, BEND3.
- chr6:131,780,721–132,401,475, 16 genes, copy number 9: AC005587.1, MIR548H5, ENPP1, SELENOKP2, RN7SKP245, AL139805.1, AL117378.1, AL117378.2, CCN2, AL133346.1, AL021408.1, MIR548AJ1, AL021408.2, LINC01013, EEF1A1P36, MOXD1.
- chr7:5,306,790–5,606,655, 13 genes, copy number 9: TNRC18, AC093620.1, AC092171.1, AC092171.4, AC092171.3, AC092171.5, FBXL18, AC092171.2, MIR589, ACTB, AC006483.2, AC006483.1, FSCN1.
- chr10:74,551,392–75,431,588, 27 genes, copy number 9: Y_RNA, NDUFA8P1, POLR3DP1, FAM32CP, AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2.
- chr10:75,450,081–75,552,553, 2 genes, copy number 9: AC010997.6, MIR606.
- chr12:68,841,288–68,971,570, 6 genes, copy number 9: AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr17:61,354,763–61,591,219, 9 genes, copy number 10: AC005746.3, AC005746.2, AC005746.1, TBX2-AS1, TBX2, LINC02875, TBX4, AC005901.1, NACA2.
- chr17:82,101,460–82,644,662, 35 genes, copy number 10 (within-gene range 2–10): CCDC57, AC129510.1, AC129510.2, AC132872.2, SLC16A3, MIR6787, CSNK1D, AC132872.3, AC132872.4, AC132872.5, LINC01970, AC132872.1, CD7, SECTM1, TEX19, AC132938.4, UTS2R, AC132938.1, OGFOD3, AC132938.2, Y_RNA, HEXD, HEXD-IT1, CYBC1, AC132938.6, AC132938.3, NARF, AC132938.5, NARF-AS1, NARF-IT1, FOXK2, AC124283.4, AC124283.3, AC124283.2, AC124283.1.
- chr20:33,055,424–33,720,319, 23 genes, copy number 9 (within-gene range 5–9): BPIFB3, BPIFB4, BPIFA2, SOCS2P1, BPIFA4P, AL121901.1, BPIFA3, BPIFA1, RPL12P3, BPIFB1, BPIFB5P, BPIFB9P, CDK5RAP1, SNTA1, CBFA2T2, AL121906.2, NECAB3, C20orf144, ACTL10, ACTL10, AL121906.1, E2F1, PXMP4.
- chr20:34,955,810–35,950,370, 44 genes, copy number 10 (within-gene range 5–10): MYH7B, MIR499A, MIR499B, TRPC4AP, RNU6-407P, EDEM2, AL135844.1, PROCR, AL356652.1, RNA5SP483, MMP24OS, MT1P3, MMP24, AL121753.2, AL121753.1, EIF6, FAM83C-AS1, FAM83C, UQCC1, GDF5-AS1, GDF5, MIR1289-1, CEP250, CEP250-AS1, FO393401.1, C20orf173, ERGIC3, RPL36P4, FER1L4, RPL37P1, SPAG4, CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12, NFS1, ROMO1, RBM39, RPF2P1, U6, PHF20, COX7BP2, Y_RNA.
- chr20:49,812,713–49,892,242, 1 gene, copy number 9 (within-gene range 5–9): SLC9A8.
- chr20:49,903,391–50,283,250, 17 genes, copy number 9: SPATA2, Y_RNA, Metazoa_SRP, RNF114, KRT18P4, RNU6-147P, SNAI1, TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON.

Autosomal genes at a single copy (total copy number 1): 45. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
